MMRF case MMRF_1311 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/739d4e3c-536a-4760-8f57-1aef50ba3f09

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.0 years (21,169 days); ISS stage: II; Days to last known disease status: 1,463 days (4.0 years); Days to last follow up: 1,463 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 242 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 252 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 281 days; Days to treatment end: 281 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 282 days; Days to treatment end: 282 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 441 days (1.2 years); Days to treatment end: 441 days (1.2 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 443 days (1.2 years); Days to treatment end: 443 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 445 days (1.2 years); Days to treatment end: 445 days (1.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,463.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 0): M Protein 3.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.462 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 2.72 g/L; Immunoglobulin A 54.3 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 4.09 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 34 g/L; Total Protein 11 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 99 (ECOG 0): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.456 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.642 mg/dL; Immunoglobulin G 8.91 g/L; Immunoglobulin A 6.24 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 161 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.496 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.637 mg/dL; Immunoglobulin G 8.88 g/L; Immunoglobulin A 4.06 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.39 mmol/L.
- Day 239 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.581 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.575 mg/dL; Immunoglobulin G 6.26 g/L; Immunoglobulin A 3.94 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.22 mmol/L.
- Day 364 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.984 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 7.75 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 1.19 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 7.18 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 8.8 mmol/L.
- Day 470 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.56 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 8.82 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.34 mmol/L.
- Day 553 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.22 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 6.2 g/dL; Glucose 7.98 mmol/L.
- Day 617 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.483 mg/dL; Immunoglobulin G 4.88 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.2 g/dL; Glucose 7.54 mmol/L.
- Day 743 (ECOG 0): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.422 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.639 mg/dL; Immunoglobulin G 6.53 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.2 g/dL; Glucose 6.22 mmol/L.
- Day 798 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.367 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.761 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.4 g/dL; Glucose 6.44 mmol/L.
- Day 889 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.417 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 6.27 mmol/L.
- Day 1,033 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.808 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.175 mg/dL; Immunoglobulin G 8.57 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 6.93 mmol/L.
- Day 1,124 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.729 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.795 mg/dL; Immunoglobulin G 8.69 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 7 g/dL; Glucose 6.49 mmol/L.
- Day 1,219 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.943 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 9.4 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 46 g/L; Total Protein 6.9 g/dL; Glucose 4.68 mmol/L.
- Day 1,310 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.871 mg/dL; Immunoglobulin G 8.78 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 6.82 mmol/L.
- Day 1,401 (ECOG 0): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.798 mg/dL; Immunoglobulin G 8.98 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 6.82 mmol/L.

Other clinical attributes
- Day -14: Weight: 130 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1311_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1311_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
